Somatic mutation profile of tumor specimen ALCH-B2OX-TTP1-A (aliquot ALCH-B2OX-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2OX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.3 years (19,110 days).
Specimen ALCH-B2OX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a33a6ac-7f69-4bc8-b270-43e31de26a3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2OX-NB1-A (Blood Derived Normal), aliquot ALCH-B2OX-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98cfbb9a-74f4-4805-a067-8c25dd6c0e9a

The open-access MAF lists 347 somatic variants for this specimen: 225 protein-altering or splice-affecting, 77 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 77, Intron 24, Nonsense Mutation 16, 3'UTR 8, Splice Site 5, Frame Shift Del 5, Splice Region 5, RNA 5, 5'Flank 4, 5'UTR 4, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>C p.Y220S | Missense Mutation (SNP) | VAF 195/310 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 113/246 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs778475793; called by muse, mutect2, varscan2
- ADCY8 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 89/506 reads (18%) | catalogued as COSV99036578; called by muse, mutect2, varscan2
- ADGRB2 | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs772780095; called by muse, mutect2, varscan2
- ADGRL3 | c.4273G>T p.E1425* (on ENST00000506720 / NM_001322402.2; = p.E1314* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 161/544 reads (30%) | catalogued as COSV72230153; called by muse, mutect2, varscan2
- AP4B1 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 175/568 reads (31%) | catalogued as rs767220480; called by muse, mutect2, varscan2
- ARFGEF3 | c.4541G>T p.R1514L | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52450670; called by muse, mutect2, varscan2
- ARHGEF10L | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.457); catalogued as rs757063935, COSV51434566; called by muse, mutect2, varscan2
- B3GAT1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs376403465, COSV56994703; called by muse, mutect2, varscan2
- BMT2 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 108/445 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as rs776234347; called by muse, mutect2, varscan2
- BUB1B | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 274/569 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as COSV99806516; called by muse, mutect2, varscan2
- C9orf78 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 306/484 reads (63%) | catalogued as COSV100204566; called by muse, mutect2, varscan2
- CACNA1E | c.4411G>T p.V1471L | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as rs915291484, COSV62385122; called by muse, mutect2, varscan2
- CARNS1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 68/203 reads (33%) | catalogued as rs776441965; called by muse, mutect2, varscan2
- CCDC168 | c.5033G>C p.G1678A | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV70555029; called by muse, mutect2, varscan2
- CFAP46 | c.6833C>T p.P2278L | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs148109095; called by muse, mutect2, varscan2
- CRLF2 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 155/404 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781459586, COSV67493389, COSV67494330; called by muse, mutect2, varscan2
- CTAG2 | c.454G>C p.G152R | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV55994469; called by muse, mutect2, varscan2
- CUX1 | c.2605C>G p.Q869E | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV52890152; called by muse, mutect2, varscan2
- DNAH6 | c.6696G>T p.M2232I | Missense Mutation (SNP) | VAF 161/553 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV52866528; called by muse, mutect2, varscan2
- DYRK4 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747416114, COSV99157999; called by muse, mutect2, varscan2
- EPHA8 | c.531C>G p.S177R | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV51264203; called by muse, mutect2, varscan2
- EPHB2 | c.1421A>G p.Y474C | Missense Mutation (SNP) | VAF 119/382 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs138869509; called by muse, mutect2, varscan2
- FHDC1 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755744077, COSV52600715; called by muse, mutect2, varscan2
- GCGR | c.657+6C>T | Splice Region (SNP) | VAF 64/211 reads (30%) | catalogued as rs1263632944; called by muse, mutect2, varscan2
- GRIN2B | c.3400C>G p.L1134V | Missense Mutation (SNP) | VAF 100/329 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.315); catalogued as rs979079013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSPT2 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 74/288 reads (26%) | catalogued as COSV61214668; called by muse, mutect2, varscan2
- HRH3 | c.1076C>A p.S359* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as COSV58050463; called by muse, mutect2, varscan2
- INPP5B | c.2548C>G p.L850V (on ENST00000373023; = p.L770V on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV65961676, COSV65962797; called by muse, mutect2, varscan2
- KIF26B | c.5090C>G p.A1697G | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs750950806, COSV63637086; called by muse, mutect2, varscan2
- KLRC1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV61724827, COSV61726161; called by muse, mutect2, varscan2
- KMT5C | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV55319231; called by muse, mutect2, varscan2
- LIMCH1 | c.936A>G p.R312= | Splice Region (SNP) | VAF 81/299 reads (27%) | catalogued as rs763924639; called by muse, mutect2, varscan2
- MAGEA1 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100756608; called by muse, mutect2, varscan2
- MCTP2 | c.1034C>G p.S345C | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV59142913; called by muse, varscan2
- MYF5 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 204/670 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57356625; called by muse, mutect2, varscan2
- MYH1 | c.3767T>C p.L1256P | Missense Mutation (SNP) | VAF 254/432 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99877310; called by muse, varscan2
- NCKAP5 | c.3804G>A p.M1268I | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1477540772, COSV58470734; called by muse, mutect2, varscan2
- NKD2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs535421197; called by muse, mutect2, varscan2
- NRF1 | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1029876343, COSV56211566; called by muse, mutect2, varscan2
- OR2J2 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs758225071; called by muse, mutect2, varscan2
- OR4K2 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 198/1042 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752743720; called by muse, mutect2, varscan2
- OR52E8 | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs140759723; called by muse, varscan2
- OR5L1 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 96/198 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61735115; called by muse, varscan2
- OR5T1 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 118/216 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs766515476; called by muse, mutect2, varscan2
- OTOF | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 105/584 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs754784459; called by muse, mutect2, varscan2
- OTUD7A | c.1814C>T p.A605V (on ENST00000307050 / NM_001382637.1; = p.A598V on NM_130901.3) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV61038323; called by muse, mutect2, varscan2
- PBX1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 97/293 reads (33%) | catalogued as COSV63345108; called by muse, mutect2, varscan2
- PDZD4 | c.1492G>A p.G498S | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0.078); catalogued as rs781875223; called by muse, mutect2, varscan2
- PI15 | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 307/636 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV52639325; called by muse, mutect2, varscan2
- PLP2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 135/411 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs868919894; called by muse, mutect2, varscan2
- PNMA3 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 34/181 reads (19%) | catalogued as rs782671536, COSV64722184; called by muse, mutect2, varscan2
- PPP1R32 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 122/186 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58546356; called by muse, mutect2, varscan2
- PPP1R32 | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 122/189 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs149840921; called by muse, mutect2, varscan2
- PSG5 | c.27C>A p.C9* | Nonsense Mutation (SNP) | VAF 110/391 reads (28%) | catalogued as rs1207475059, COSV61655660; called by muse, mutect2, varscan2
- PSG9 | c.199T>C p.W67R | Missense Mutation (SNP) | VAF 167/506 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52484481; called by muse, mutect2, varscan2
- PTPRO | c.1913C>T p.T638I | Missense Mutation (SNP) | VAF 168/538 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs372101904; called by muse, mutect2, varscan2
- RGS7 | c.364del p.E122Sfs*86 | Frame Shift Del (DEL) | VAF 276/733 reads (38%) | catalogued as COSV58535665; called by mutect2, pindel, varscan2
- SETDB1 | c.2587G>T p.V863L | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54988153; called by muse, mutect2, varscan2
- SLC22A11 | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 88/325 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs200429766, COSV57255193; called by muse, mutect2, varscan2
- SMAD4 | c.1334G>C p.R445P | Missense Mutation (SNP) | VAF 166/568 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV61687696; called by muse, mutect2, varscan2
- SPEG | c.7489G>C p.E2497Q | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs927713192; called by muse, mutect2, varscan2
- SYPL2 | c.527C>A p.T176N | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs373200737; called by muse, mutect2, varscan2
- TNN | c.2452G>T p.D818Y | Missense Mutation (SNP) | VAF 115/369 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53426415; called by muse, mutect2, varscan2
- UGT1A5 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 125/357 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV59383635; called by muse, mutect2, varscan2
- VBP1 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 137/327 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs1255749615; called by muse, mutect2, varscan2
- VEGFD | c.1036del p.Q346Rfs*22 | Frame Shift Del (DEL) | VAF 104/432 reads (24%) | catalogued as COSV52909779; called by mutect2, pindel, varscan2
- VSTM2B | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 142/487 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs966039137; called by muse, mutect2, varscan2
- ZDHHC18 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs768006137; called by muse, mutect2, varscan2
- ZFHX4 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 124/262 reads (47%) | catalogued as COSV51461556; called by muse, mutect2, varscan2
- ABCC2 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 87/401 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACIN1 | c.1352A>T p.Q451L | Missense Mutation (SNP) | VAF 201/344 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ACTL8 | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 106/356 reads (30%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4024A>T p.I1342F (on ENST00000506720 / NM_001322402.2; = p.I1231F on NM_015236.6) | Missense Mutation (SNP) | VAF 140/480 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- AKNA | c.3257G>T p.R1086L | Missense Mutation (SNP) | VAF 193/336 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANK2 | c.447G>C p.L149F | Missense Mutation (SNP) | VAF 178/558 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKUB1 | c.954A>T p.Q318H | Missense Mutation (SNP) | VAF 96/399 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP5F1E | c.15G>C p.W5C | Missense Mutation (SNP) | VAF 62/489 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BRI3BP | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1C | c.5187C>A p.H1729Q | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.917); called by muse, varscan2
- CACNA1C | c.5345C>T p.A1782V | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, varscan2
- CAPG | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CARMIL2 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- CCDC181 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | called by muse, mutect2, varscan2
- CCDC28A | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC66 | c.902T>A p.I301K (on ENST00000394672 / NM_001353147.1; = p.I267K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD163L1 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDKL4 | c.1053G>T p.M351I | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP89 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 79/269 reads (29%) | called by muse, mutect2, varscan2
- CFAP44 | c.4979A>G p.Q1660R | Missense Mutation (SNP) | VAF 132/646 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHEK2 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST11 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 139/512 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- COLGALT2 | c.1492C>A p.L498M | Missense Mutation (SNP) | VAF 199/646 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CT55 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CYP2D7 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DCAF8L2 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 118/395 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DNAH7 | c.10108G>C p.E3370Q | Missense Mutation (SNP) | VAF 115/415 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DNAJC6 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 124/415 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DPP6 | c.2510G>T p.R837L (on ENST00000377770 / NM_001364500.2; = p.R775L on NM_001936.5) | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- DRD1 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EFCAB6 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- EID2B | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EPG5 | c.4330-1G>T p.X1444_splice | Splice Site (SNP) | VAF 132/448 reads (29%) | called by muse, mutect2, varscan2
- EPHA10 | c.323C>A p.T108K | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERBB4 | c.2498A>G p.Y833C | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM47C | c.1547A>G p.E516G | Missense Mutation (SNP) | VAF 165/613 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FCRL5 | c.2812+1G>T p.X938_splice | Splice Site (SNP) | VAF 68/208 reads (33%) | called by muse, varscan2
- FGFBP1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLCN | c.1301-1G>A p.X434_splice | Splice Site (SNP) | VAF 158/495 reads (32%) | called by muse, mutect2, varscan2
- FLCN | c.1275G>C p.Q425H | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.054); called by muse, varscan2
- FLG2 | c.5360A>T p.Q1787L | Missense Mutation (SNP) | VAF 105/349 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- FLT3 | c.1230G>T p.K410N | Missense Mutation (SNP) | VAF 105/266 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GALNT17 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- GEN1 | c.2379G>C p.K793N | Missense Mutation (SNP) | VAF 99/296 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GGTLC2 | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 210/553 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAI3 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- GOLPH3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.115); called by muse, mutect2
- GPR143 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GPR158 | c.3016G>T p.V1006L | Missense Mutation (SNP) | VAF 211/504 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- GRID2 | c.456G>T p.L152F | Missense Mutation (SNP) | VAF 186/564 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- HDAC6 | c.3579+1G>A p.X1193_splice | Splice Site (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- HELZ | c.4152G>C p.Q1384H | Missense Mutation (SNP) | VAF 166/551 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- HIPK2 | c.949A>T p.S317C | Missense Mutation (SNP) | VAF 128/429 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HOXD11 | c.806A>G p.K269R | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HSF2 | c.1068A>T p.G356= | Splice Region (SNP) | VAF 70/235 reads (30%) | called by muse, mutect2, varscan2
- HTR3D | c.157_159del p.I53del | In Frame Del (DEL) | VAF 81/570 reads (14%) | called by mutect2, pindel, varscan2
- HTRA1 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 293/562 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, varscan2
- HYAL4 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 107/342 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGSF5 | c.62del p.A21Gfs*22 | Frame Shift Del (DEL) | VAF 80/233 reads (34%) | called by mutect2, pindel, varscan2
- IL1RAPL1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 105/453 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITIH6 | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNC4 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF19 | c.2127C>A p.H709Q | Missense Mutation (SNP) | VAF 103/437 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRBA1 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- KRBA1 | c.2642C>A p.T881K | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- KRTAP9-9 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 274/853 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- L1CAM | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- L1TD1 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 96/385 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LCORL | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- LRRK2 | c.2136G>T p.M712I | Missense Mutation (SNP) | VAF 131/445 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRRK2 | c.2137C>A p.L713I | Missense Mutation (SNP) | VAF 130/447 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRTM4 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 133/428 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAGEA3 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 234/526 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, varscan2
- MAP3K15 | c.1589C>A p.P530Q | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- MARCKS | c.614_634del p.A205_S211del | In Frame Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- MGAT5 | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MPRIP | c.770G>C p.C257S | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- MTDH | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 244/465 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MUC16 | c.27838A>G p.T9280A | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MYH13 | c.1991C>G p.T664S | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MYO7A | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 207/326 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- MYO9A | c.6212A>T p.E2071V | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYT1 | c.2129C>T p.P710L | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NALCN | c.4025T>A p.M1342K | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NCOA6 | c.5442T>G p.S1814R | Missense Mutation (SNP) | VAF 140/401 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- NEK10 | c.1167A>T p.A389= | Splice Region (SNP) | VAF 116/215 reads (54%) | called by muse, mutect2, varscan2
- NEUROD4 | c.687C>G p.F229L | Missense Mutation (SNP) | VAF 98/377 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NME8 | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); called by muse, varscan2
- NMT1 | c.129G>T p.R43= | Splice Region (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- NPTX2 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUCB1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OPHN1 | c.731A>T p.E244V | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2T12 | c.241G>C p.A81P | Missense Mutation (SNP) | VAF 300/715 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); called by muse, varscan2
- OTOL1 | c.803A>C p.K268T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- OTOL1 | c.948A>T p.K316N | Missense Mutation (SNP) | VAF 91/348 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PAN2 | c.2098G>C p.D700H (on ENST00000425394 / NM_001127460.3; = p.D696H on NM_014871.5) | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PAN2 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 152/483 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PCDH11X | c.794del p.G265Afs*4 | Frame Shift Del (DEL) | VAF 98/306 reads (32%) | called by mutect2, pindel, varscan2
- PDGFRA | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 157/611 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PHLDB1 | c.4120C>T p.Q1374* | Nonsense Mutation (SNP) | VAF 85/102 reads (83%) | called by muse, mutect2, varscan2
- PIKFYVE | c.3461A>G p.D1154G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PKHD1L1 | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 124/578 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PKHD1L1 | c.964T>A p.C322S | Missense Mutation (SNP) | VAF 112/461 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLCH1 | c.4949G>T p.R1650L (on ENST00000340059 / NM_001130960.2; = p.R1642L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 202/392 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLPPR5 | c.805T>G p.C269G | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- PLXND1 | c.2959G>T p.E987* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- PPP1R37 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP1R37 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PRDX4 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 117/411 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PREX2 | c.3567G>T p.K1189N | Missense Mutation (SNP) | VAF 111/519 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- PRIMPOL | c.1257T>G p.C419W | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR32 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 139/408 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- RB1CC1 | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 197/798 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFX4 | c.1780C>A p.H594N (on ENST00000392842 / NM_213594.3; = p.H500N on NM_032491.6) | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- RYR1 | c.11236G>C p.E3746Q | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SETD2 | c.2141G>C p.C714S | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3KBP1 | c.1976A>G p.K659R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SIGLEC6 | c.155G>T p.R52I | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SLC22A6 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 104/390 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- SLC30A3 | c.188C>A p.P63Q | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC39A10 | c.1964_1965dup p.H656Vfs*7 | Frame Shift Ins (INS) | VAF 81/358 reads (23%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLFN14 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SOX5 | c.863G>C p.R288P | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A6 | c.1360_1361del p.C454Pfs*61 | Frame Shift Del (DEL) | VAF 124/414 reads (30%) | called by mutect2, pindel, varscan2
- SPIDR | c.1078G>T p.V360F | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- SPPL2C | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 132/426 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- STK36 | c.3893C>G p.S1298C | Missense Mutation (SNP) | VAF 99/404 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SULF1 | c.467G>C p.W156S | Missense Mutation (SNP) | VAF 82/351 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SYNE2 | c.15692A>T p.Q5231L | Missense Mutation (SNP) | VAF 290/394 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SZT2 | c.5794G>A p.A1932T (on ENST00000634258 / NM_001365999.1; = p.A1875T on NM_015284.4) | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TAF1 | c.1445T>C p.L482P (on ENST00000373790 / NM_138923.4; = p.L503P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TBR1 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 111/454 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEP1 | c.6884C>T p.A2295V | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.019); called by muse, mutect2
- TMEM185A | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 158/571 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM231 | c.805G>T p.A269S (on ENST00000258173 / NM_001077418.3; = p.A298S on NM_001077416.2) | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNR | c.499+2T>C p.X167_splice | Splice Site (SNP) | VAF 25/81 reads (31%) | called by muse, varscan2
- TRABD2A | c.380T>A p.L127Q | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAT1 | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 104/535 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TRIOBP | c.6458C>T p.A2153V (on ENST00000644935 / NM_001039141.3; = p.A440V on NM_007032.5) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- TRPA1 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 176/841 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TTC3 | c.5300A>C p.H1767P | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTI1 | c.1132C>G p.L378V | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TTN | c.9892C>A p.L3298I (on ENST00000591111; = p.L3252I on NM_003319.4) | Missense Mutation (SNP) | VAF 190/563 reads (34%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBA7 | c.1304A>G p.Y435C | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UBE2M | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UTP23 | c.714A>T p.K238N | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- VPS13C | c.4141G>C p.V1381L (on ENST00000644861 / NM_020821.3; = p.V1338L on NM_017684.5) | Missense Mutation (SNP) | VAF 86/328 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VRK2 | c.83A>T p.Q28L | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, varscan2
- WDR17 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- WDR27 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ZCRB1 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ZNF541 | c.2972G>T p.C991F | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF585A | c.776T>C p.M259T (on ENST00000292841 / NM_001288800.2; = p.M204T on NM_152655.3) | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.263); called by muse, mutect2
- ZNF729 | c.2048C>A p.P683Q | Missense Mutation (SNP) | VAF 178/414 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- ABCA13 | c.14385G>T p.T4795= | Silent (SNP) | VAF 56/182 reads (31%) | catalogued as COSV68946832; called by muse, mutect2, varscan2
- ACTRT1 | c.807C>T p.G269= | Silent (SNP) | VAF 87/287 reads (30%) | called by muse, mutect2, varscan2
- ADHFE1 | c.21C>T p.A7= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs1235431068; called by muse, mutect2, varscan2
- ARAF | c.1707G>T p.L569= | Silent (SNP) | VAF 47/139 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.2382C>T p.L794= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs1557102338, COSV61685721; called by muse, mutect2, varscan2
- B4GALNT2 | c.1212C>A p.L404= | Silent (SNP) | VAF 50/268 reads (19%) | called by muse, mutect2, varscan2
- BCAT2 | c.408G>T p.L136= | Silent (SNP) | VAF 58/173 reads (34%) | called by muse, mutect2, varscan2
- C10orf120 | c.30G>A p.Q10= | Silent (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- C1orf167 | c.2793C>A p.A931= | Silent (SNP) | VAF 61/234 reads (26%) | called by muse, mutect2, varscan2
- CACNA1E | c.1768C>A p.R590= | Silent (SNP) | VAF 64/206 reads (31%) | catalogued as rs760975849, COSV62380904; called by muse, varscan2
- CADPS2 | c.1482G>T p.L494= | Silent (SNP) | VAF 84/326 reads (26%) | called by muse, mutect2, varscan2
- CAND2 | c.1498C>T p.L500= (on ENST00000456430 / NM_001162499.2; = p.L407= on NM_012298.3) | Silent (SNP) | VAF 56/121 reads (46%) | called by muse, mutect2, varscan2
- CCDC160 | c.108G>A p.T36= | Silent (SNP) | VAF 44/364 reads (12%) | catalogued as rs759528450; called by muse, mutect2, varscan2
- CD5 | c.639G>A p.L213= | Silent (SNP) | VAF 283/438 reads (65%) | called by muse, mutect2, varscan2
- CDK16 | c.573G>T p.V191= | Silent (SNP) | VAF 104/343 reads (30%) | called by muse, mutect2, varscan2
- CEP250 | c.1593G>T p.L531= | Silent (SNP) | VAF 66/182 reads (36%) | called by muse, mutect2, varscan2
- CST9L | c.153G>A p.V51= | Silent (SNP) | VAF 135/554 reads (24%) | called by muse, mutect2, varscan2
- CYFIP2 | c.291A>G p.K97= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as rs774593356; called by muse, mutect2, varscan2
- DPP6 | c.2334G>T p.A778= (on ENST00000377770 / NM_001364500.2; = p.A716= on NM_001936.5) | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as COSV100125845, COSV100126911; called by muse, mutect2, varscan2
- EPHA2 | c.702C>T p.A234= | Silent (SNP) | VAF 104/350 reads (30%) | catalogued as rs145881684; called by muse, mutect2, varscan2
- EPHA3 | c.1083C>T p.I361= | Silent (SNP) | VAF 57/557 reads (10%) | called by muse, mutect2, varscan2
- EPHA6 | c.1828C>A p.R610= | Silent (SNP) | VAF 182/604 reads (30%) | called by muse, mutect2, varscan2
- ETV5 | c.984A>G p.E328= | Silent (SNP) | VAF 103/560 reads (18%) | called by muse, mutect2, varscan2
- EXTL1 | c.81C>T p.F27= | Silent (SNP) | VAF 78/210 reads (37%) | catalogued as rs1199054011; called by muse, mutect2, varscan2
- FSHR | c.1851C>T p.I617= | Silent (SNP) | VAF 155/446 reads (35%) | called by muse, mutect2, varscan2
- GALNT17 | c.957C>T p.P319= | Silent (SNP) | VAF 66/203 reads (33%) | catalogued as COSV61198132; called by muse, mutect2, varscan2
- GPR174 | c.453C>A p.L151= | Silent (SNP) | VAF 114/219 reads (52%) | catalogued as COSV52132714; called by muse, mutect2, varscan2
- GRIN3A | c.1978C>A p.R660= | Silent (SNP) | VAF 283/415 reads (68%) | catalogued as COSV100701713; called by muse, mutect2, varscan2
- INSIG1 | c.774G>C p.T258= | Silent (SNP) | VAF 136/546 reads (25%) | catalogued as COSV100453164; called by muse, mutect2, varscan2
- ITGB4 | c.405C>T p.L135= | Silent (SNP) | VAF 95/296 reads (32%) | catalogued as rs1473277617; called by muse, mutect2, varscan2
- KCND1 | c.126G>T p.L42= | Silent (SNP) | VAF 61/208 reads (29%) | called by muse, mutect2, varscan2
- KCP | c.4254C>T p.G1418= (on ENST00000620378; = p.G1542= on NM_001366122.1) | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- KRTAP2-3 | c.12C>A p.S4= | Silent (SNP) | VAF 69/301 reads (23%) | called by muse, mutect2, varscan2
- LAMA5 | c.10203C>T p.F3401= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as rs757890325, COSV53357113; called by muse, mutect2, varscan2
- LIG4 | c.2352T>C p.S784= | Silent (SNP) | VAF 114/257 reads (44%) | called by muse, mutect2, varscan2
- LMTK3 | c.3894G>A p.A1298= | Silent (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- LRP1B | c.5445G>C p.R1815= | Silent (SNP) | VAF 88/256 reads (34%) | catalogued as COSV101258008; called by muse, mutect2, varscan2
- LRRIQ4 | c.370C>A p.R124= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as rs1012245295, COSV61619125; called by muse, mutect2, varscan2
- MTUS1 | c.1344G>A p.T448= | Silent (SNP) | VAF 313/473 reads (66%) | catalogued as rs369320389; called by muse, mutect2, varscan2
- MYBPC1 | c.2196G>T p.T732= (on ENST00000550270 / NM_206820.2; = p.T757= on NM_002465.4) | Silent (SNP) | VAF 333/1019 reads (33%) | called by muse, mutect2, varscan2
- NBPF10 | c.264A>G p.Q88= | Silent (SNP) | VAF 241/850 reads (28%) | catalogued as rs1553797887; called by muse, mutect2, varscan2
- NOTCH2 | c.1183C>T p.L395= | Silent (SNP) | VAF 204/628 reads (32%) | catalogued as rs782633421, COSV56706546; called by muse, mutect2, varscan2
- NRGN | c.75C>G p.G25= | Silent (SNP) | VAF 90/160 reads (56%) | catalogued as rs1317128159; called by muse, mutect2, varscan2
- OR1B1 | c.774C>T p.Y258= | Silent (SNP) | VAF 130/173 reads (75%) | catalogued as rs142453546; called by muse, varscan2
- OR2T10 | c.453G>T p.V151= | Silent (SNP) | VAF 94/347 reads (27%) | called by muse, mutect2, varscan2
- OR2T10 | c.9G>T p.L3= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV57897840; called by muse, mutect2, varscan2
- OR4Q3 | c.231C>T p.F77= | Silent (SNP) | VAF 48/561 reads (9%) | catalogued as COSV59178100, COSV59179076; called by muse, mutect2
- OR5AS1 | c.474C>A p.V158= | Silent (SNP) | VAF 175/348 reads (50%) | called by muse, mutect2, varscan2
- PAX1 | c.99C>T p.L33= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- PCDHA4 | c.1038T>C p.N346= | Silent (SNP) | VAF 95/201 reads (47%) | catalogued as rs535812009; called by muse, mutect2, varscan2
- PCDHB14 | c.2163G>C p.S721= | Silent (SNP) | VAF 134/294 reads (46%) | catalogued as COSV53390589; called by muse, mutect2, varscan2
- PDE2A | c.2286G>A p.R762= | Silent (SNP) | VAF 132/230 reads (57%) | catalogued as COSV57813496; called by muse, mutect2, varscan2
- PDE4DIP | c.2979G>A p.P993= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as rs368904679; called by muse, varscan2
- PDE8A | c.240T>A p.L80= | Silent (SNP) | VAF 94/283 reads (33%) | called by muse, mutect2, varscan2
- PDIA4 | c.1272C>T p.F424= (on ENST00000286091 / NM_001371244.1; = p.F423= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, varscan2
- PLB1 | c.2310A>G p.G770= | Silent (SNP) | VAF 114/295 reads (39%) | catalogued as rs762536125; called by muse, mutect2, varscan2
- PRAMEF11 | c.102C>A p.P34= | Silent (SNP) | VAF 175/614 reads (29%) | called by muse, mutect2, varscan2
- PRAMEF8 | c.51G>T p.L17= | Silent (SNP) | VAF 81/306 reads (26%) | called by muse, mutect2, varscan2
- RNF113A | c.576C>T p.T192= | Silent (SNP) | VAF 93/277 reads (34%) | catalogued as COSV65097034; called by muse, mutect2, varscan2
- ROBO4 | c.2856C>A p.P952= | Silent (SNP) | VAF 182/291 reads (63%) | called by muse, mutect2, varscan2
- RREB1 | c.105G>T p.G35= | Silent (SNP) | VAF 140/277 reads (51%) | called by muse, mutect2, varscan2
- SEC63 | c.318T>C p.Y106= | Silent (SNP) | VAF 121/231 reads (52%) | catalogued as rs745574021; called by muse, mutect2, varscan2
- SLC26A3 | c.1296G>T p.L432= | Silent (SNP) | VAF 259/798 reads (32%) | called by muse, mutect2, varscan2
- SLC4A1 | c.2292C>A p.L764= | Silent (SNP) | VAF 119/415 reads (29%) | called by muse, mutect2, varscan2
- SMG1 | c.9337C>T p.L3113= | Silent (SNP) | VAF 133/259 reads (51%) | catalogued as rs1401319319; called by muse, mutect2, varscan2
- SNX4 | c.1089T>C p.F363= | Silent (SNP) | VAF 133/594 reads (22%) | catalogued as rs141423057; called by muse, mutect2, varscan2
- SPATA31E1 | c.1284G>T p.V428= | Silent (SNP) | VAF 144/280 reads (51%) | called by muse, mutect2, varscan2
- SYT16 | c.1101C>A p.L367= | Silent (SNP) | VAF 436/699 reads (62%) | called by muse, mutect2, varscan2
- TARM1 | c.513A>G p.A171= (on ENST00000616041 / NM_001330650.1; = p.A163= on NM_001135686.3) | Silent (SNP) | VAF 158/514 reads (31%) | called by muse, mutect2, varscan2
- TBR1 | c.762G>T p.V254= | Silent (SNP) | VAF 111/452 reads (25%) | catalogued as COSV67417518; called by muse, mutect2, varscan2
- TENT5D | c.315A>G p.L105= | Silent (SNP) | VAF 146/313 reads (47%) | called by muse, mutect2, varscan2
- TMEM80 | c.483C>T p.D161= | Silent (SNP) | VAF 79/165 reads (48%) | called by muse, mutect2, varscan2
- TOP3B | c.429C>T p.G143= | Silent (SNP) | VAF 71/286 reads (25%) | catalogued as rs752451136, COSV100592500; called by muse, mutect2, varscan2
- TP53I13 | c.48C>T p.L16= | Silent (SNP) | VAF 67/243 reads (28%) | catalogued as rs202018922; called by muse, mutect2, varscan2
- TTN | c.75108T>C p.T25036= (on ENST00000591111; = p.T17612= on NM_003319.4) | Silent (SNP) | VAF 73/304 reads (24%) | catalogued as rs1256950839; called by muse, mutect2, varscan2
- ZNF548 | c.1521C>A p.S507= | Silent (SNP) | VAF 60/192 reads (31%) | called by muse, varscan2
- ZNF827 | c.1309C>T p.L437= | Silent (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2
- AGER | c.991+12G>C | Intron (SNP) | VAF 63/148 reads (43%) | called by muse, mutect2, varscan2
- AICDA | c.427+11G>C | Intron (SNP) | VAF 102/412 reads (25%) | called by muse, mutect2, varscan2
- AKAP17A | c.1152+46C>G | Intron (SNP) | VAF 70/236 reads (30%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823993 A>G | 5'Flank (SNP) | VAF 61/118 reads (52%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.170G>C | RNA (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- C5orf17 | n.213C>A | RNA (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- CABP5 | c.-44del | 5'UTR (DEL) | VAF 5/35 reads (14%) | catalogued as COSV99506455, COSV99506765; called by pindel, varscan2
- CYP2W1 | c.1285+70G>A | Intron (SNP) | VAF 24/58 reads (41%) | catalogued as rs769729184; called by muse, mutect2, varscan2
- DMGDH | c.2250+2639G>C | Intron (SNP) | VAF 122/370 reads (33%) | called by muse, mutect2, varscan2
- DPP6 | c.627+21021C>G | Intron (SNP) | VAF 101/381 reads (27%) | called by muse, mutect2, varscan2
- EDIL3 | c.*28C>T | 3'UTR (SNP) | VAF 182/375 reads (49%) | catalogued as rs866912366; called by muse, mutect2, varscan2
- EIF4G3 | c.1495+169A>G | Intron (SNP) | VAF 76/239 reads (32%) | called by muse, mutect2, varscan2
- ELP4 | c.1146+31839G>T | Intron (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- FBXW7 | c.502-2607T>C | Intron (SNP) | VAF 74/189 reads (39%) | called by muse, mutect2, varscan2
- GABRE | c.784+1182G>A | Intron (SNP) | VAF 13/344 reads (4%) | called by muse, mutect2
- HDAC6 | chrX:48801921 G>T | 5'Flank (SNP) | VAF 59/228 reads (26%) | called by muse, mutect2, varscan2
- HDDC3 | c.168+30T>A | Intron (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1928T>A | RNA (SNP) | VAF 76/321 reads (24%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-1239A>T | Intron (SNP) | VAF 40/115 reads (35%) | called by muse, mutect2, varscan2
- MAP3K15 | c.1749-1263A>G | Intron (SNP) | VAF 17/77 reads (22%) | called by muse, varscan2
- NFKBIA | c.*14G>A | 3'UTR (SNP) | VAF 410/727 reads (56%) | catalogued as rs768552445; called by muse, mutect2, varscan2
- NR0B1 | c.*16A>T | 3'UTR (SNP) | VAF 140/528 reads (27%) | called by muse, mutect2, varscan2
- PAK5 | c.*2C>T | 3'UTR (SNP) | VAF 46/129 reads (36%) | catalogued as COSV62034481; called by muse, mutect2, varscan2
- PCCB | c.373-138G>C | Intron (SNP) | VAF 76/163 reads (47%) | called by muse, mutect2, varscan2
- PMM1 | c.282+9C>T | Intron (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- PRKCG | c.-190C>T | 5'UTR (SNP) | VAF 5/16 reads (31%) | catalogued as COSV54726813; called by muse, mutect2, varscan2
- QSOX1 | c.*1347G>A | 3'UTR (SNP) | VAF 8/146 reads (5%) | catalogued as rs1001219503; called by muse, mutect2
- RASSF4 | c.139-152C>T | Intron (SNP) | VAF 47/157 reads (30%) | called by muse, mutect2, varscan2
- RBM43 | c.3+339G>C | Intron (SNP) | VAF 197/591 reads (33%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.2887C>G | RNA (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- RUFY4 | c.1614-191G>T | Intron (SNP) | VAF 61/197 reads (31%) | called by muse, mutect2, varscan2
- RYR2 | c.14151+19C>T | Intron (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2, varscan2
- SIGMAR1 | c.*49C>T | 3'UTR (SNP) | VAF 114/303 reads (38%) | catalogued as rs1327719378; called by muse, mutect2, varscan2
- SLC2A10 | c.-85C>T | 5'UTR (SNP) | VAF 64/150 reads (43%) | catalogued as COSV100826428; called by muse, mutect2, varscan2
- SMPX | c.-71T>C | 5'UTR (SNP) | VAF 187/570 reads (33%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2106del | RNA (DEL) | VAF 206/486 reads (42%) | called by mutect2, pindel*, varscan2
- SPG7 | c.1642+21G>T | Intron (SNP) | VAF 76/129 reads (59%) | called by muse, mutect2, varscan2
- SULF1 | c.*528G>A | 3'UTR (SNP) | VAF 274/594 reads (46%) | called by muse, mutect2, varscan2
- TBC1D30 | c.*2708A>T | 3'UTR (SNP) | VAF 96/417 reads (23%) | called by muse, mutect2, varscan2
- TPTE2 | c.1395+693C>A | Intron (SNP) | VAF 31/155 reads (20%) | catalogued as rs777367503; called by muse, mutect2, varscan2
- TPTE2 | c.1395+692C>A | Intron (SNP) | VAF 33/161 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.10360+4999G>C | Intron (SNP) | VAF 249/834 reads (30%) | called by muse, varscan2
- ZAN | c.7787+18A>C | Intron (SNP) | VAF 57/153 reads (37%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149777311 G>T | 5'Flank (SNP) | VAF 25/94 reads (27%) | called by muse, varscan2
- ZNF467 | chr7:149777318 del G | 5'Flank (DEL) | VAF 16/74 reads (22%) | called by pindel, varscan2
